Somatic mutation profile of tumor specimen TARGET-10-PARFTR-03A (aliquot TARGET-10-PARFTR-03A-01D) from TARGET case TARGET-10-PARFTR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,127 days).
Specimen TARGET-10-PARFTR-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69cb1c29-af5b-48de-ad35-e771f331fd7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFTR-10A (Blood Derived Normal), aliquot TARGET-10-PARFTR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5c7eee3-25f4-4a01-8efe-1466c23c488e

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 2, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHF6 | c.820C>T p.R274* (on ENST00000332070 / NM_032458.3; = p.R275* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 223/292 reads (76%) | catalogued as rs1556019107, COSV59699330; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTB | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); catalogued as COSV59316567, COSV59319474; called by muse, mutect2
- AXIN1 | c.498C>A p.S166R | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51983181; called by muse, mutect2, varscan2
- SETD2 | c.4792C>T p.R1598* | Nonsense Mutation (SNP) | VAF 143/355 reads (40%) | catalogued as COSV57429911; called by muse, mutect2, varscan2
- SLCO2B1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs375353895, COSV56932942; called by muse, mutect2, varscan2
- ABI3 | c.88_89insGGCACGAGG p.V29_A30insGHE | In Frame Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel
- LRRC4 | c.861C>T p.T287= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV50813205; called by muse, mutect2, varscan2
- UBR4 | c.13780C>T p.L4594= | Silent (SNP) | VAF 54/147 reads (37%) | catalogued as COSV64382769; called by muse, mutect2, varscan2
- STX4 | c.*2G>A | 3'UTR (SNP) | VAF 63/151 reads (42%) | catalogued as COSV58267801; called by muse, mutect2, varscan2
